Surgical pathology report (de-identified scan), TCGA case TCGA-2L-AAQE, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Technical University of Munich, specimen TCGA-2L-AAQE-01A (Primary Tumor).

[page 1 of 2]
100-3
Adenocarcinoma, duct NOS 850013
Site: Pancreas head C25.0
JAS 6/5/14

Age: male

Surgery date:

Macroscopic evaluation

1. Pancreatic head: unfixed, an irregular, partially indurated, 2 cm in diameter tissue specimen
2. Cutting edge of the pancreas: unfixed, pancreas lamellae with central ductus pancreaticus, 3x2x0.5 cm
3. Skin nodule abdominal wall: fixed, spindle-shaped 3.5x0.8x1 cm large Skin/Hypoderm resection specimen. Above the skin a 0.6 cm in diameter exophytic brown-grey knot with a lobate surface. The knot is located 0.1 cm away from the lateral resection margin, towards the top of the spindles minimum 0.5 cm. Embedding of the top of the spindles and the central parts in relation to the papillary knot.
4. Gall bladder: fixed, a 8.5x4x1.2 cm large gall bladder, resected after 0.5 cm from the D. cysticus. The lumen of the gall bladder is filled with coagulated blood. At the branching of the D. cysticus a 1.2 cm large lymph node.
5. Lymph node A. hepatica: fixed, fragmented fatty tissue, in total 4x3x1 cm with multiple max. 3 cm large partially fragmented lymph nodes.
6. Liver hilum: soft tissue: fixed, fragmented soft tissue, in total max. 3 cm with multiple max. 3 cm large grey-glass-like lymph nodes.
7. Pancreatic head: fixed, resection specimen pancreas/duodenum, composed of a 30 cm long small intestine and a 8.5x7.5x4.5 cm large pancreas head. Centrally within the pancreatic head a 3.5x6x3.5 cm large cyst, corresponding with the widened pancreas duct. The cyst was opened intra surgically from ventral with single sutures more than 6 cm. The cyst was reddish-brown covered, the adjacent tissue grey/glass-like. Caudal to the cyst a 4.5x4x3 cm large diffusely defined dense tumor with solid grey/glass-like margin. Infiltration into the adjacent fatty tissue dorsal and medial. Peripancreatic lymph nodes max. 1.2 cm. Distances of the tumor to the resection margins: medial 0.1 cm, dorsal 0.3 cm, resection margin pancreas distal 0.5 cm. Several max. 1.2 cm large peripancreatic lymph nodes. Ink mark: resection margin medial: green, dorsal black, ventral blue.
A.-C. a central cross section of the tumor in relation to the resection margin and the cyst.
D. cyst in relation to the tumor and the intra-surgical opening ventral.
E. Cyst in relation to the bile duct
F. resection margin pancreas distal and resection margin bile duct (tangential)
G. aboral resection margin duodenum
H. oral resection margin duodenum
J.-K. lymph nodes upper rim of the pancreas
L.-M. lymph nodes lower rim of the pancreas
8. Omentum majus: fixed, a 26x12x0.7 cm large omentum with focal fresh hemorrhages. No tumor.

Instantaneous section report

1. Adenocarcinoma
2. without tumor

Processed: 19 blocks, H&E, 1xEvG, 1xPAS, 2x instantaneous section

Microscopy

1. Confirmation of the diagnosis made by instantaneous section, invasive glandular adenocarcinoma
2. Confirmation of the diagnosis made by instantaneous section, resection margin without tumor

[page 2 of 2]
3. Naevus, papillary, dermal. Within the healthy tissue, benign.
4. Gall bladder without tumor, fresh hemorrhages and leucocyte infiltration, most likely due to the surgery. Lymph node without tumor.
5. Metastasis-free lymph nodes (0/3)
6. Metastasis-free lymph nodes (0/3)
7. Block A without tumor. Block B invasive carcinoma, glandular growth pattern, partially highly dissociated with abortive glands and solid tumor cell nests, focus forming just moderately. Partially large complex glands. The proliferation is moderate, continuous infiltration of a lymph node. Infiltration of the peripancreatic soft tissue. Marked chronic and acute pancreatitis with extensive fibrosis, partially ductectasia. Formation of a pseudo cyst. Chronic erosive inflammation in ductus choledochus with regenerating epithelium. Enteric resection margins without tumor. Chronic lymphadenitis and partially perilymphadenitis or perinodular soft tissue infiltration due to the carcinoma. Additional lymph nodes without tumor (0/13)
8. Omentum majus without malignancy, moderate fibrosis of the serosa, fresh leucocyte infiltration with hemorrhage, due to the surgery.

Short report on diagnostic findings

Pancreatic carcinoma (head)

Moderately differentiated invasive ductal adenocarcinoma, tumor size max. 4.5 cm. Infiltration of the peripancreatic soft tissue. Single regional lymph node metastases peripancreatically at the main specimen (1/15).

Severe chronic fibrotic pancreatitis with pancreatic pseudocyst (8.). Enteric, parenchymatous, and deeper resection margins all without tumor (2., 7.).

Omentum majus without tumor with focal fibrosis (8.).

Chronic cholecystitis with metastasis-free lymph node at the D. cysticus (4.).

Metastases-free lymph nodes at the A.hepatica (0/3) (5.) and metastasis-free lymph nodes at the liver hilum (0/3) (6.).

TNM classification (UICC, 7th Edition 2010): pT3, pN1 (1/22), cM0, Pn1, L0, V0, R0, G2.

Source: NCI Genomic Data Commons file e6aa9836-8c7a-4fd9-ad16-2782e0635af6 (TCGA-2L-AAQE.139BF7AF-2E19-44A4-ACD5-E343C89E34D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).